Somatic mutation profile of tumor specimen ASCProject_0165_T2_WES (aliquot ASCProject_0165_T2_WES_1) from CMI case ASCProject_0165, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: male; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Skin of scalp and neck; Age at diagnosis: 62.5 years (22,836 days).
Specimen ASCProject_0165_T2_WES: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Scalp; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9f68e80-c754-4a98-8305-fd70b34b37e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0165_BLOOD_BC (Buffy Coat), aliquot ASCProject_0165_BLOOD_BC_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad2ff81e-affd-45c6-8300-19d4ebe9dc5f

The open-access MAF lists 1,635 somatic variants for this specimen: 943 protein-altering or splice-affecting, 461 silent, 231 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 845, Silent 461, Intron 87, Nonsense Mutation 50, RNA 42, 3'UTR 36, 5'UTR 26, 5'Flank 24, Splice Region 20, Splice Site 17, 3'Flank 16, Frame Shift Del 6.

Variants (750 of 1,635; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL7A1 | c.6110G>A p.G2037E | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912846, CM990415; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DPYD | c.1681C>T p.R561* | Nonsense Mutation (SNP) | VAF 45/193 reads (23%) | catalogued as rs1057516968, CM161357, COSV64613429; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KNSTRN | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 66/202 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as rs766760890, COSV51111003, COSV99992101; called by muse, varscan2
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 73/220 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 53/146 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.14411C>T p.P4804L | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs1186280695; called by muse, mutect2, varscan2
- ABCC1 | c.749C>T p.S250L | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1567335064; called by muse, mutect2, varscan2
- ABCC6 | c.2692G>A p.D898N | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.287); catalogued as rs778911783, COSV52746539; called by muse, mutect2, varscan2
- AC011005.1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 66/235 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs770707544; called by muse, mutect2, varscan2
- ACTR5 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs202044751, COSV54759889; called by muse, mutect2, varscan2
- ADAM21 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs764758775, COSV50799211; called by muse, varscan2
- ADAM30 | c.1534G>A p.G512R | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104428692; called by muse, mutect2, varscan2
- ADAMTS20 | c.2402C>T p.S801L | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760555816, COSV67129800, COSV67132864; called by muse, mutect2, varscan2
- ADAMTSL2 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1281902576; called by muse, mutect2, varscan2
- ADAT2 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.358); catalogued as rs959711687, COSV99395589; called by muse, mutect2, varscan2
- ADAT2 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV52794132; called by muse, mutect2, varscan2
- ADGRA3 | c.3206C>T p.S1069L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as rs1458329968; called by muse, mutect2, varscan2
- ADGRB3 | c.955G>A p.V319I | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65411268; called by muse, mutect2, varscan2
- ADGRF1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs1463423725; called by muse, mutect2
- ADGRG4 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757361583, COSV99795215; called by muse, mutect2, varscan2
- ADGRV1 | c.6130T>A p.S2044T | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.326); catalogued as COSV101315758; called by muse, mutect2, varscan2
- ADNP2 | c.3203C>T p.P1068L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as COSV51539133; called by muse, mutect2, varscan2
- ADRA1B | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as COSV60701866; called by muse, mutect2, varscan2
- AGBL1 | c.903G>A p.E301= | Splice Region (SNP) | VAF 34/131 reads (26%) | catalogued as COSV66850232; called by muse, mutect2, varscan2
- AIPL1 | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV100006036; called by muse, mutect2, varscan2
- AJAP1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0.202); catalogued as rs759413505; called by muse, mutect2, varscan2
- AKAP9 | c.4204C>T p.P1402S | Missense Mutation (SNP) | VAF 95/282 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs1187172089; called by muse, mutect2, varscan2
- ALCAM | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV60249459; called by muse, mutect2, varscan2
- ALDH16A1 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV53196842; called by muse, mutect2, varscan2
- ALK | c.2777G>A p.G926E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1490348940, COSV66589966; called by muse, mutect2, varscan2
- ALPK3 | c.1876G>A p.G626R | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51935921; called by muse, mutect2, varscan2
- AMY2B | c.1454C>G p.S485C | Missense Mutation (SNP) | VAF 59/446 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV100796556; called by muse, mutect2, varscan2
- ANKRD18A | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV68804774; called by muse, mutect2, varscan2
- ANO1 | c.2603G>A p.R868Q | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100796915; called by muse, mutect2, varscan2
- APOBEC4 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.307); catalogued as COSV58018256; called by muse, mutect2, varscan2
- APOBEC4 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.586); catalogued as rs765193470; called by muse, mutect2, varscan2
- ARAP2 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs765116606, COSV58288243; called by muse, mutect2, varscan2
- ARHGAP22 | c.1192G>A p.G398R | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as COSV50933586; called by muse, mutect2, varscan2
- ARHGEF4 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.006); catalogued as rs762720636; called by muse, mutect2, varscan2
- ASAP2 | c.2897C>T p.S966F | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.069); catalogued as rs762610686, COSV53007212; called by muse, mutect2, varscan2
- ASPSCR1 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs760536415; called by muse, mutect2, varscan2
- ASXL3 | c.5438G>A p.G1813E | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52466499; called by muse, mutect2, varscan2
- ATG2A | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs895177073, COSV101034701, COSV65967843; called by muse, varscan2
- ATG2B | c.5577T>A p.H1859Q | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV55890817; called by muse, mutect2, varscan2
- ATP6V0D2 | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV53414967, COSV53415362; called by muse, mutect2
- AUNIP | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs927853126; called by muse, mutect2, varscan2
- AXIN1 | c.2008C>T p.L670F | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.051); catalogued as rs1281159388, COSV51993855; called by muse, mutect2
- BAIAP2 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.125); catalogued as COSV100348668; called by muse, mutect2, varscan2
- BCAN | c.1253G>A p.S418N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs147658469, COSV61260250; called by muse, mutect2, varscan2
- BDP1 | c.2137C>T p.P713S | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1220533099; called by muse, mutect2, varscan2
- BDP1 | c.2138C>T p.P713L | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs368015863; called by muse, mutect2, varscan2
- BFSP2 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs189376399; called by muse, mutect2, varscan2
- BLK | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 78/138 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs765828168; called by muse, mutect2, varscan2
- BPI | c.329C>T p.S110F (on ENST00000262865; = p.S106F on NM_001725.3) | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as COSV53403974; called by muse, mutect2, varscan2
- BRINP1 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.456); catalogued as rs151087333, COSV56292314; called by muse, mutect2, varscan2
- BRPF1 | c.2248C>T p.P750S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs778390528; called by muse, mutect2
- C1orf68 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as COSV64224456; called by muse, mutect2, varscan2
- C22orf31 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV99326270; called by muse, mutect2, varscan2
- C22orf31 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); catalogued as rs756258158; called by muse, mutect2, varscan2
- C9 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 52/178 reads (29%) | catalogued as rs754943606, COSV54674270; called by muse, mutect2, varscan2
- CACNA1D | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs769128755; called by muse, mutect2, varscan2
- CACNA1E | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as rs369308237; called by muse, mutect2, varscan2
- CACNA1S | c.1318C>T p.L440F | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.037); catalogued as rs760734614; called by muse, mutect2, varscan2
- CACNA2D3 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.101); catalogued as rs865798465, COSV55540495; called by muse, mutect2, varscan2
- CADPS | c.2593G>A p.D865N | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as COSV51876366; called by muse, mutect2, varscan2
- CAMK1G | c.1132G>A p.G378S | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV50524493; called by muse, mutect2, varscan2
- CAPZA3 | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777853511; called by muse, mutect2, varscan2
- CBY2 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60117963, COSV60118038; called by muse, mutect2
- CCDC138 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs763016292, COSV54567381; called by muse, mutect2, varscan2
- CCDC151 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV62698184; called by muse, mutect2, varscan2
- CCDC168 | c.16381C>T p.P5461S | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as rs1038411998, COSV59422353; called by muse, mutect2, varscan2
- CCDC168 | c.9337G>A p.E3113K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as rs761797818, COSV59422520; called by muse, mutect2, varscan2
- CCDC17 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.306); catalogued as rs868446642; called by muse, mutect2, varscan2
- CCDC178 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV55763999; called by muse, mutect2, varscan2
- CCDC27 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as COSV53900934; called by muse, mutect2, varscan2
- CCDC96 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs755169672; called by muse, mutect2, varscan2
- CCKAR | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as COSV55164636; called by muse, mutect2, varscan2
- CCN3 | c.1064G>A p.G355E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1563617931; called by muse, mutect2
- CCT4 | c.1606-5A>T | Splice Region (SNP) | VAF 58/201 reads (29%) | catalogued as COSV101075138; called by muse, mutect2, varscan2
- CD163L1 | c.3239G>A p.G1080E | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs983471052, COSV100550112, COSV58023500; called by muse, mutect2, varscan2
- CD3E | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 72/331 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs780235352, COSV62345395; called by muse, mutect2, varscan2
- CD79A | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99702053; called by muse, mutect2, varscan2
- CDC14C | c.1492G>A p.E498K (on ENST00000428251; = p.E391K on NM_152627.3) | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs758667733; called by muse, mutect2, varscan2
- CDCA7L | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.144); catalogued as COSV60967177; called by muse, mutect2, varscan2
- CDH10 | c.1152T>A p.F384L | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100051875; called by muse, mutect2, varscan2
- CDH11 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51759808; called by muse, mutect2, varscan2
- CDH3 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV50558641; called by muse, mutect2
- CDH5 | c.1862G>A p.R621Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs1327918298, COSV58516486, COSV58517750; called by muse, mutect2, varscan2
- CERKL | c.1237+1G>A p.X413_splice (on ENST00000339098 / NM_001030311.2; = p.X387_splice on NM_201548.5) | Splice Site (SNP) | VAF 70/290 reads (24%) | catalogued as rs1364032336; called by muse, mutect2, varscan2
- CFAP221 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1374001131; called by muse, mutect2, varscan2
- CFAP46 | c.6172C>T p.L2058F | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); catalogued as rs748541524; called by muse, mutect2, varscan2
- CFAP47 | c.2785G>A p.G929R | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52892000; called by muse, mutect2, varscan2
- CFAP54 | c.8815C>T p.P2939S | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.46); PolyPhen benign (0.325); catalogued as rs12582405; called by muse, mutect2, varscan2
- CHRNB2 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as rs1215936429, COSV63807684; called by muse, mutect2, varscan2
- CIC | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.165); catalogued as rs267605512; called by muse, mutect2, varscan2
- CLIP2 | c.2761C>T p.R921C | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99791133, COSV99792397; called by muse, mutect2, varscan2
- CLIP4 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 66/217 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV104410756; called by muse, mutect2, varscan2
- CNKSR3 | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs769891155, COSV101401272; called by muse, varscan2
- CNNM2 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 77/281 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs746746121, COSV64001591; called by muse, mutect2, varscan2
- CNR1 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV62986622; called by muse, mutect2, varscan2
- CNTN2 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as COSV59353367; called by muse, mutect2, varscan2
- CNTN5 | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as rs868416804, COSV99681065; called by muse, mutect2, varscan2
- CNTNAP5 | c.3049C>T p.P1017S | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV70487540; called by muse, mutect2, varscan2
- COL13A1 | c.2000G>A p.G667E (on ENST00000398978 / NM_001130103.2; = p.G595E on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62567028; called by muse, mutect2, varscan2
- COL19A1 | c.2560G>A p.G854S | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1418753311; called by muse, mutect2, varscan2
- COL22A1 | c.4160G>A p.G1387E | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100278254; called by muse, mutect2, varscan2
- COL22A1 | c.3746G>A p.G1249E | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100279111; called by muse, mutect2, varscan2
- COL24A1 | c.1946G>A p.R649K | Missense Mutation (SNP) | VAF 85/327 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs374585874; called by muse, mutect2, varscan2
- COL4A1 | c.2675C>T p.S892L | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.061); catalogued as rs747751840; called by muse, mutect2, varscan2
- COL4A3 | c.4946C>T p.T1649I | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101170001; called by muse, varscan2
- COL4A4 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 93/283 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757578262; called by muse, varscan2
- COLEC11 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 98/196 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350837390, COSV99363457; called by muse, mutect2, varscan2
- CORIN | c.686T>C p.M229T | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.725); catalogued as rs1483602148; called by muse, mutect2, varscan2
- CPEB4 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs373430313; called by muse, mutect2
- CR2 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.1); catalogued as rs909956111, COSV100889496; called by muse, mutect2, varscan2
- CRLF1 | c.855G>A p.K285= | Splice Region (SNP) | VAF 41/110 reads (37%) | catalogued as rs1568440540; called by muse, mutect2, varscan2
- CROT | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 114/162 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV58976922; called by muse, mutect2, varscan2
- CRYGA | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs1001389914; called by muse, mutect2, varscan2
- CSMD1 | c.7772C>A p.P2591H (on ENST00000520002; = p.P2590H on NM_033225.6) | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59385103; called by muse, mutect2, varscan2
- CSMD1 | c.6460C>T p.Q2154* (on ENST00000520002; = p.Q2153* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 24/43 reads (56%) | catalogued as COSV59382419; called by muse, mutect2, varscan2
- CSMD3 | c.4667C>T p.P1556L (on ENST00000297405 / NM_001363185.1; = p.P1452L on NM_052900.3) | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99832795; called by muse, mutect2, varscan2
- CSMD3 | c.1465C>T p.P489S (on ENST00000297405 / NM_001363185.1; = p.P385S on NM_052900.3) | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342353387, COSV52142838; called by muse, mutect2
- CTSG | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV99361661; called by mutect2, varscan2
- CYP11B1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as rs762414385, CD147560; called by muse, mutect2, varscan2
- CYP2C9 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as CM1412012; called by muse, mutect2, varscan2
- CYP4X1 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs1482764172; called by muse, mutect2, varscan2
- DCDC2B | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.497); catalogued as rs774230311; called by muse, mutect2, varscan2
- DCLK3 | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69363298; called by muse, mutect2, varscan2
- DCST1 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as rs763686878, COSV55061388; called by muse, mutect2, varscan2
- DDHD2 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.766); catalogued as rs554950617; called by muse, mutect2, varscan2
- DDX12P | n.2560C>T | Splice Region (SNP) | VAF 11/173 reads (6%) | catalogued as rs1413033847; called by muse, mutect2
- DENND5B | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as rs1437341049; called by muse, mutect2, varscan2
- DENND6A | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310118866; called by muse, mutect2, varscan2
- DEPDC5 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 13/87 reads (15%) | catalogued as COSV56708581; called by muse, mutect2, varscan2
- DGCR8 | c.1859C>T p.P620L | Missense Mutation (SNP) | VAF 123/239 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1009437344; called by muse, mutect2, varscan2
- DIRAS2 | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1459468281; called by muse, mutect2, varscan2
- DMBT1 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.86); PolyPhen benign (0.054); catalogued as COSV57543457; called by muse, mutect2, varscan2
- DMBT1 | c.2351G>A p.G784E | Missense Mutation (SNP) | VAF 73/263 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs1202998169, COSV57566645; called by muse, mutect2, varscan2
- DNAH14 | c.4519C>T p.R1507* (on ENST00000445597; = p.R1912* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 50/207 reads (24%) | catalogued as rs930272445, COSV60737076; called by muse, mutect2, varscan2
- DNAH5 | c.11176C>T p.Q3726* | Nonsense Mutation (SNP) | VAF 39/114 reads (34%) | catalogued as rs867684159, COSV54208224; called by muse, mutect2, varscan2
- DNAH5 | c.6274G>A p.E2092K | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs865876907, COSV54246857; called by muse, mutect2, varscan2
- DNAH9 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868374603; called by muse, mutect2
- DNAI1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 72/242 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as COSV54281801; called by muse, mutect2, varscan2
- DOK6 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV66934197; called by muse, mutect2, varscan2
- DPYD | c.2512C>T p.L838F | Missense Mutation (SNP) | VAF 92/226 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1292887398; called by muse, mutect2, varscan2
- DYNC1I1 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 30/246 reads (12%) | catalogued as COSV100269140, COSV61456238; called by muse, mutect2, varscan2
- DYNC1I1 | c.1801C>T p.R601C | Missense Mutation (SNP) | VAF 146/210 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1452319389, COSV100269739, COSV61466179; called by muse, mutect2, varscan2
- ENAM | c.2816G>A p.R939K | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.046); catalogued as rs752376600, COSV101252837; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENPP2 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.834); catalogued as rs1427093740; called by muse, mutect2, varscan2
- EPB41L3 | c.1462G>A p.G488R | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs375665706; called by muse, mutect2, varscan2
- ESPNL | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs751400186; called by muse, mutect2, varscan2
- ETS2 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.823); catalogued as rs868010226; called by muse, mutect2, varscan2
- FAAH2 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 58/88 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1254403222, COSV66506076, COSV66506223; called by muse, mutect2, varscan2
- FAM193A | c.3023C>T p.P1008L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as COSV61198535; called by muse, mutect2, varscan2
- FAM53A | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); catalogued as rs1161951281; called by muse, mutect2, varscan2
- FAM83A | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs758055707; called by muse, mutect2, varscan2
- FAT2 | c.5599G>A p.D1867N | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1476158737; called by muse, mutect2, varscan2
- FAT2 | c.5383G>A p.E1795K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV55815197, COSV55829946; called by muse, mutect2
- FAT4 | c.8701C>T p.P2901S | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.998); catalogued as rs139451014, COSV58677035; called by muse, mutect2, varscan2
- FBH1 | c.1019G>A p.G340E (on ENST00000362091 / NM_178150.3; = p.G391E on NM_032807.4) | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV100758987; called by muse, mutect2, varscan2
- FBN2 | c.4036G>A p.G1346R | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs368522099; called by muse, mutect2, varscan2
- FCAR | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.24); catalogued as COSV62032136; called by muse, mutect2, varscan2
- FGD5 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as rs921327158, COSV99548065; called by muse, mutect2, varscan2
- FHOD3 | c.2486C>T p.P829L (on ENST00000359247 / NM_001281739.3; = p.P846L on NM_025135.5) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1333935514; called by muse, mutect2, varscan2
- FLG | c.8318G>A p.S2773N | Missense Mutation (SNP) | VAF 34/501 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs755462597; called by muse, mutect2
- FLG | c.2477G>A p.R826Q | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs762159918, COSV64236056; called by muse, varscan2
- FLG | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV100911601; called by muse, mutect2, varscan2
- FLRT3 | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as rs1031673015, COSV99434923; called by muse, mutect2, varscan2
- FOXN4 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as rs763175655; called by muse, varscan2
- FREM2 | c.8336C>T p.S2779F | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV54836352; called by muse, mutect2, varscan2
- FREM2 | c.8616G>A p.W2872* | Nonsense Mutation (SNP) | VAF 63/226 reads (28%) | catalogued as rs755903580; called by muse, mutect2, varscan2
- FRMD3 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 50/154 reads (32%) | catalogued as rs370741927; called by muse, mutect2, varscan2
- FRMPD1 | c.4495C>T p.Q1499* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV66699292; called by muse, mutect2, varscan2
- FSCB | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV61218002; called by muse, mutect2, varscan2
- FSCN1 | c.878C>T p.T293I | Missense Mutation (SNP) | VAF 87/160 reads (54%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.87); catalogued as rs1168885809; called by muse, mutect2, varscan2
- FSD1 | c.1267G>A p.G423S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55698533; called by muse, mutect2, varscan2
- FSIP2 | c.19298C>T p.S6433L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100554824; called by muse, mutect2, varscan2
- FUT9 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV100133274, COSV100133413; called by muse, mutect2, varscan2
- GABRA1 | c.851T>C p.V284A | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as rs794727962; ClinVar: conflicting interpretations of pathogenicity; called by muse, varscan2
- GABRB2 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as COSV50935119; called by muse, mutect2, varscan2
- GCN1 | c.5615C>T p.A1872V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs780831734; called by muse, mutect2, varscan2
- GIPC1 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs749007977; called by muse, mutect2, varscan2
- GOLGA8J | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs762152014; called by muse, mutect2, varscan2
- GPAA1 | c.1246C>T p.L416F | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1554764160; called by muse, mutect2, varscan2
- GPR179 | c.1445G>A p.R482Q (on ENST00000621958; = p.R481Q on NM_001004334.4) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as rs749359646; called by muse, mutect2, varscan2
- GPR63 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV100013131; called by muse, mutect2, varscan2
- GRIA2 | c.2144G>A p.R715Q | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52397881; called by muse, mutect2, varscan2
- GRID2 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56218303; called by muse, mutect2, varscan2
- GRIN2B | c.3430C>T p.P1144S | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as rs1245220591; called by muse, mutect2, varscan2
- GYS2 | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 84/241 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1040299197; called by muse, mutect2, varscan2
- HAO1 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs148598378; called by muse, mutect2, varscan2
- HAVCR2 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as rs868862244; called by muse, mutect2, varscan2
- HECW1 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67840675; called by muse, mutect2, varscan2
- HECW2 | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs750964845, COSV99646599; called by muse, mutect2, varscan2
- HIC2 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV68042792; called by muse, mutect2, varscan2
- HIVEP2 | c.4121C>T p.T1374I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV50073593; called by muse, mutect2, varscan2
- HNRNPCL2 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV60403318; called by muse, mutect2, varscan2
- HRH3 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs917156919; called by muse, mutect2, varscan2
- HRNR | c.6511G>A p.G2171S | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.019); catalogued as COSV64262212; called by muse, mutect2, varscan2
- HTRA3 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56473496; called by muse, mutect2, varscan2
- HYAL4 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0.011); catalogued as COSV56139009; called by muse, mutect2, varscan2
- HYOU1 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375666355; called by muse, mutect2, varscan2
- IL13 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs201475069, COSV58733981; called by muse, mutect2, varscan2
- IL37 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54490299; called by muse, mutect2, varscan2
- IMPG1 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.254); catalogued as rs760355051; called by muse, mutect2, varscan2
- INSL5 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs754889887; called by muse, mutect2, varscan2
- IRF5 | c.1384C>T p.H462Y | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.685); catalogued as rs1239660357; called by muse, mutect2, varscan2
- ITGA4 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 67/193 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV51999848; called by muse, mutect2, varscan2
- KCNA5 | c.1603C>T p.L535F | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV52904741; called by muse, mutect2, varscan2
- KCNC3 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.586); catalogued as rs748735877, COSV65388920; called by muse, mutect2, varscan2
- KCNH7 | c.2408G>A p.G803E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV59814471; called by muse, mutect2
- KCNK13 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99965965; called by muse, mutect2, varscan2
- KCNS2 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1398212581, COSV54639393, COSV99751133; called by muse, mutect2, varscan2
- KIAA1614 | c.2453C>T p.S818L | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs371498831; called by muse, mutect2, varscan2
- KIT | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.022); catalogued as COSV55387819; called by muse, mutect2, varscan2
- KLHL34 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV101069943; called by muse, mutect2, varscan2
- KMT2D | c.8555C>T p.S2852F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1471272445, COSV56413534; called by muse, mutect2
- KNSTRN | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV99991886; called by muse, varscan2
- KREMEN1 | c.824C>T p.T275I (on ENST00000407188; = p.T277I on NM_032045.5) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs971202099; called by muse, mutect2, varscan2
- KRT10 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV54088916; called by muse, mutect2, varscan2
- KRT14 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.255); catalogued as COSV51423264, COSV99069946; called by mutect2, varscan2
- KRT3 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1213370734, COSV58817043; called by muse, mutect2, varscan2
- KRT82 | c.1112G>A p.G371D | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1176081489; called by muse, mutect2, varscan2
- KRTAP19-4 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.119); catalogued as COSV61859054; called by muse, mutect2, varscan2
- KRTAP26-1 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779471216; called by muse, mutect2, varscan2
- KYNU | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1391979281; called by muse, mutect2, varscan2
- LAMA1 | c.5062C>T p.P1688S | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.019); catalogued as rs1355368277; called by muse, mutect2, varscan2
- LAMC2 | c.2126G>A p.G709E | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs759613276, COSV99917051; called by muse, mutect2, varscan2
- LGMN | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100605964; called by muse, mutect2, varscan2
- LHX3 | c.817T>C p.Y273H (on ENST00000371748 / NM_178138.6; = p.Y278H on NM_014564.5) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs753061107; called by mutect2, varscan2
- LPA | c.3065G>A p.W1022* | Nonsense Mutation (SNP) | VAF 34/99 reads (34%) | catalogued as COSV60306969; called by muse, mutect2, varscan2
- LRFN2 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57829236, COSV57835020; called by muse, mutect2, varscan2
- LRP1B | c.12160G>A p.E4054K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.67); catalogued as COSV67287198; called by muse, varscan2
- LRP2 | c.5189G>A p.G1730E | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752089581, COSV55575542; called by muse, mutect2, varscan2
- LRP2 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV55548350; called by muse, varscan2
- LRRC40 | c.74C>T p.T25I | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs773622048; called by muse, mutect2, varscan2
- LRRC4C | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53418262; called by muse, mutect2, varscan2
- LRRK2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.334); catalogued as COSV54144654; called by muse, mutect2, varscan2
- LRRK2 | c.4297C>T p.P1433S | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1309698515; called by muse, mutect2, varscan2
- LUZP4 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 47/68 reads (69%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64219218; called by muse, mutect2, varscan2
- MADD | c.1592C>T p.S531L | Missense Mutation (SNP) | VAF 116/376 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs749517991; called by muse, mutect2, varscan2
- MAP1B | c.3761C>T p.S1254L | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as rs770358379, COSV57106001; called by muse, mutect2, varscan2
- MAST1 | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV52240895; called by muse, mutect2, varscan2
- MBOAT2 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs955335450, COSV60012040; called by muse, mutect2, varscan2
- MCF2L2 | c.2776C>T p.R926* | Nonsense Mutation (SNP) | VAF 62/115 reads (54%) | catalogued as rs1442450988, COSV61055570; called by muse, mutect2, varscan2
- MED13L | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 133/1070 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56117409; called by muse, mutect2, varscan2
- MEFV | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV54819647; called by muse, mutect2, varscan2
- METTL11B | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.589); catalogued as COSV63029487; called by muse, mutect2, varscan2
- MGAM | c.4333C>T p.P1445S | Missense Mutation (SNP) | VAF 116/174 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs3087313; called by muse, mutect2, varscan2
- MGAM | c.4334C>T p.P1445L | Missense Mutation (SNP) | VAF 114/171 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV72076076; called by muse, mutect2, varscan2
- MICALL2 | c.2053C>T p.P685S | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs751456779; called by muse, mutect2, varscan2
- MISP | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs768424472; called by muse, mutect2, varscan2
- MMP9 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 84/271 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV63433882; called by muse, mutect2, varscan2
- MOXD1 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as rs751748575, COSV60950545; called by muse, mutect2, varscan2
- MPRIP | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as rs773137931; called by muse, mutect2, varscan2
- MROH2B | c.4256G>A p.G1419E | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.63); catalogued as COSV68185515; called by muse, mutect2, varscan2
- MTUS2 | c.1609C>T p.H537Y | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs773094787; called by muse, mutect2, varscan2
- MUC12 | c.686G>A p.S229N (on ENST00000379442; = p.S86N on NM_001164462.1) | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.22); catalogued as rs1368847188; called by muse, mutect2, varscan2
- MUC16 | c.34168G>A p.D11390N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.044); catalogued as rs141026380; called by mutect2, varscan2
- MUC16 | c.33560C>T p.S11187F | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV67481005; called by muse, mutect2, varscan2
- MUC16 | c.25168G>A p.E8390K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs746342432, COSV67490499; called by mutect2, varscan2
- MYCBPAP | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV60406503; called by muse, mutect2, varscan2
- MYCN | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 75/224 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55257391, COSV55257848; called by muse, mutect2, varscan2
- MYH2 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 19/95 reads (20%) | catalogued as rs769712128; called by muse, mutect2, varscan2
- MYH4 | c.3889G>A p.E1297K | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs267604704, COSV55124239; called by muse, mutect2, varscan2
- MYH7 | c.3790G>A p.E1264K | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV100805562; called by muse, mutect2, varscan2
- MYH8 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV101238649; called by muse, mutect2, varscan2
- MYL1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV61681269; called by muse, varscan2
- MYO10 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.696); catalogued as rs1236705785; called by muse, mutect2, varscan2
- MYO3A | c.3576G>A p.M1192I | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV56349084; called by muse, mutect2, varscan2
- MYO7B | c.3862G>A p.E1288K | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs758529828, COSV67346180; called by muse, mutect2, varscan2
- MYOM1 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); catalogued as rs1324366209, COSV55288068; called by muse, mutect2, varscan2
- MYPN | c.3553G>A p.E1185K | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs145923914; called by muse, mutect2, varscan2
- NAP1L2 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV65173085; called by muse, mutect2, varscan2
- NCAPD3 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV73257830; called by muse, mutect2, varscan2
- NCKAP5L | c.3617C>T p.P1206L | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.116); catalogued as rs550998532, COSV100259243; called by muse, mutect2, varscan2
- NCKAP5L | c.3616C>T p.P1206S | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV100258952; called by muse, mutect2, varscan2
- NECAB3 | c.940C>T p.R314* (on ENST00000246190 / NM_031232.4; = p.R280* on NM_031231.4) | Nonsense Mutation (SNP) | VAF 40/117 reads (34%) | catalogued as rs771179131, COSV55777424; called by muse, mutect2, varscan2
- NELL2 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as COSV61576337; called by muse, mutect2, varscan2
- NETO1 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV55009842; called by muse, mutect2, varscan2
- NLRP14 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV55065736; called by muse, mutect2, varscan2
- NLRP14 | c.2158G>A p.D720N | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV55070328; called by muse, mutect2, varscan2
- NLRP4 | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs868450451, COSV56715942; called by muse, mutect2, varscan2
- NLRX1 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52702801; called by muse, mutect2, varscan2
- NOL4L | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.242); catalogued as rs371649171, COSV62890143; called by muse, mutect2, varscan2
- NOS1 | c.1440G>A p.W480* | Nonsense Mutation (SNP) | VAF 16/122 reads (13%) | catalogued as COSV57615524; called by muse, mutect2, varscan2
- NOTCH2 | c.5647C>T p.L1883F | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56693734; called by muse, mutect2, varscan2
- NOTCH4 | c.2336G>A p.G779E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100900541, COSV66682808; called by muse, mutect2
- NOX5 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as rs973932321; called by muse, mutect2, varscan2
- NPAP1 | c.2626C>T p.P876S | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); catalogued as rs146008809, COSV61508675; called by muse, mutect2, varscan2
- NR4A3 | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV58249134; called by muse, mutect2, varscan2
- NRXN1 | c.4186G>A p.E1396K | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs1303134658, COSV99046038; called by muse, mutect2, varscan2
- NSUN7 | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57273564; called by muse, mutect2, varscan2
- NUF2 | c.1125G>A p.E375= | Splice Region (SNP) | VAF 43/125 reads (34%) | catalogued as COSV99616172; called by muse, mutect2, varscan2
- NWD2 | c.1619G>A p.R540Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1266803458; called by muse, varscan2
- OAZ3 | c.303G>A p.S101= | Splice Region (SNP) | VAF 20/48 reads (42%) | catalogued as COSV100162582; called by muse, mutect2, varscan2
- OR13J1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs779397899; called by muse, mutect2, varscan2
- OR2A5 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 92/238 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV68738979; called by muse, mutect2, varscan2
- OR2B3 | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs757133933; called by muse, mutect2, varscan2
- OR2L13 | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100813835; called by muse, mutect2, varscan2
- OR2M2 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1157951794; called by muse, mutect2, varscan2
- OR4M1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs760327097, COSV60059765, COSV60060322, COSV60060528; called by muse, mutect2, varscan2
- OR4N2 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.856); catalogued as COSV60054313; called by muse, mutect2, varscan2
- OR4P4 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as rs868382984, COSV58920644; called by muse, mutect2, varscan2
- OR51G2 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58993815; called by muse, mutect2, varscan2
- OR51I1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs776940989, COSV66507733; called by mutect2, varscan2
- OR52K2 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1347218585, COSV57835093; called by muse, mutect2, varscan2
- OR52N1 | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs769182013, COSV57693320; called by muse, mutect2, varscan2
- OR8K5 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756900844, COSV57889897, COSV57889909; called by muse, mutect2, varscan2
- PABPC5 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as COSV57043196; called by muse, mutect2, varscan2
- PABPN1L | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV104396146; called by muse, mutect2
- PAK5 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV62026659; called by muse, mutect2, varscan2
- PAWR | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV60925526; called by muse, mutect2, varscan2
- PAX3 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 51/245 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs1364517233, COSV60586764; called by muse, mutect2, varscan2
- PCDHAC1 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.491); catalogued as COSV53837231; called by muse, mutect2, varscan2
- PCDHB4 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554274440, COSV52020064; called by muse, mutect2, varscan2
- PCDHGB2 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV54048370; called by muse, mutect2, varscan2
- PCDHGB4 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53930736; called by muse, mutect2, varscan2
- PCNT | c.9995C>T p.P3332L | Missense Mutation (SNP) | VAF 68/265 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs572189125; called by muse, mutect2, varscan2
- PCNX3 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs946620141, COSV58421592; called by muse, mutect2, varscan2
- PCNX3 | c.5761C>T p.P1921S | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.027); catalogued as rs1450820699; called by muse, mutect2, varscan2
- PDE1B | c.1530T>G p.I510M | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.496); catalogued as COSV99226422; called by muse, mutect2, varscan2
- PDE3A | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV62974473; called by muse, mutect2
- PDE9A | c.1724C>T p.T575I | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs1251482372; called by muse, mutect2, varscan2
- PDHA1 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 74/134 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs776360150; called by muse, mutect2, varscan2
- PDK3 | c.752A>G p.N251S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64794199; called by muse, mutect2, varscan2
- PDZD2 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1303175012, COSV99225197; called by muse, mutect2
- PENK | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs573652413, COSV59240213, COSV59242061; called by muse, mutect2, varscan2
- PGAM4 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 68/124 reads (55%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1440539287, COSV100430508; called by muse, mutect2, varscan2
- PGPEP1L | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1366936463; called by muse, mutect2, varscan2
- PITPNM2 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748798586; called by muse, mutect2, varscan2
- PKD1 | c.4808C>T p.S1603F | Missense Mutation (SNP) | VAF 98/266 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99238985; called by muse, mutect2, varscan2
- PLAG1 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57610826; called by muse, mutect2, varscan2
- PLCG2 | c.2984C>T p.S995L | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100842152; called by muse, mutect2, varscan2
- PLEKHH2 | c.2721G>A p.K907= | Splice Region (SNP) | VAF 45/140 reads (32%) | catalogued as rs747641127; called by muse, mutect2, varscan2
- PLEKHN1 | c.805G>A p.E269K (on ENST00000379409; = p.E217K on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as rs970356587; called by muse, mutect2, varscan2
- POT1 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 85/114 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62935205; called by muse, mutect2, varscan2
- PPEF2 | c.62A>G p.K21R | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as rs770933484; called by muse, mutect2, varscan2
- PPP1R13B | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV52448411; called by muse, mutect2, varscan2
- PPP2R2B | c.166G>A p.E56K (on ENST00000394409; = p.E122K on NM_181674.2) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs1450701618; called by muse, mutect2, varscan2
- PPP4R4 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV58556641; called by muse, mutect2, varscan2
- PRAMEF11 | c.139A>G p.S47G | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.108); catalogued as rs1292254502, COSV71306576; called by muse, mutect2, varscan2
- PREX2 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV55780900; called by muse, mutect2, varscan2
- PRPH2 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as rs1203908646; called by muse, mutect2, varscan2
- PRR23B | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV100272030; called by muse, mutect2, varscan2
- PRSS54 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753720837; called by muse, mutect2, varscan2
- PSG8 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60609435; called by muse, mutect2, varscan2
- PTCD1 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 92/145 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs753527469, COSV52857207; called by muse, mutect2, varscan2
- PTGER2 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV55418191; called by muse, mutect2, varscan2
- PTGIS | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as rs778170334; called by muse, mutect2, varscan2
- PTK7 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745721306, COSV57846263; called by muse, mutect2, varscan2
- PTK7 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57848571; called by muse, mutect2, varscan2
- PTPRO | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs373962189; called by muse, mutect2, varscan2
- PXDNL | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); catalogued as rs757058225, COSV62485102; called by muse, mutect2, varscan2
- RARRES2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as COSV99784700; called by muse, mutect2, varscan2
- RERGL | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57461681; called by muse, mutect2, varscan2
- RET | c.2846G>A p.G949E | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60706194; called by muse, mutect2, varscan2
- RFX6 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.007); catalogued as rs1364016225; called by muse, mutect2, varscan2
- RGS7 | c.1111A>C p.K371Q | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.191); catalogued as COSV100466454; called by muse, mutect2, varscan2
- RIMBP2 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV55473457; called by muse, mutect2, varscan2
- RNF111 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as rs1246716711, COSV62086205; called by muse, mutect2
- ROBO2 | c.874A>G p.M292V | Missense Mutation (SNP) | VAF 111/249 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1481975496; called by muse, mutect2, varscan2
- RORC | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59091553; called by muse, mutect2, varscan2
- ROS1 | c.4840C>T p.P1614S | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV63862834; called by muse, mutect2, varscan2
- RP1 | c.2276G>A p.R759K | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs868697369, COSV55117337, COSV55125832; called by muse, mutect2, varscan2
- RYR1 | c.6070C>T p.P2024S | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.242); catalogued as rs779178878; called by muse, mutect2, varscan2
- RYR1 | c.13453G>A p.E4485K | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.982); catalogued as rs1345911103; called by muse, mutect2, varscan2
- RYR2 | c.13238C>T p.P4413L | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100769528; called by muse, mutect2, varscan2
- RYR3 | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754630934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL1 | c.356T>G p.L119R | Missense Mutation (SNP) | VAF 98/324 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV51763599, COSV51764465; called by muse, varscan2
- SAMD9L | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as rs1179342886; called by muse, mutect2, varscan2
- SCN10A | c.1603G>A p.G535S | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV71861202; called by muse, mutect2, varscan2
- SCN2A | c.2468G>A p.W823* | Nonsense Mutation (SNP) | VAF 44/145 reads (30%) | catalogued as rs1553578424; called by muse, mutect2, varscan2
- SEC14L1 | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.153); catalogued as rs747124708; called by muse, mutect2, varscan2
- SELE | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV60976471; called by muse, mutect2, varscan2
- SELENON | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 117/367 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs766798515, COSV100823506; ClinVar: uncertain significance; called by muse, mutect2
- SEMA6B | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56702331; called by muse, mutect2, varscan2
- SEMA6C | c.2260C>T p.P754S | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.986); catalogued as rs1443398368; called by muse, mutect2, varscan2
- SERINC2 | c.451C>T p.P151S (on ENST00000373709 / NM_178865.5; = p.P155S on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101037107; called by muse, varscan2
- SERPINA11 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 36/92 reads (39%) | catalogued as rs1360643413; called by muse, mutect2, varscan2
- SERPINB13 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.768); catalogued as COSV54028834; called by muse, mutect2, varscan2
- SFTPA1 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100956856; called by muse, mutect2, varscan2
- SHCBP1L | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62357160; called by muse, mutect2, varscan2
- SHROOM3 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 83/299 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as rs1384304635, COSV56029556; called by muse, mutect2, varscan2
- SIGLEC1 | c.4414G>A p.G1472R | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.025); catalogued as rs759889163; called by muse, mutect2, varscan2
- SIGLEC9 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.142); catalogued as rs151265101; called by muse, mutect2, varscan2
- SIGLECL1 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as rs948535377, COSV57063316, COSV57064615; called by muse, mutect2, varscan2
- SLC10A5 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 54/252 reads (21%) | catalogued as rs763311140; called by muse, mutect2, varscan2
- SLC15A5 | c.895C>T p.H299Y | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.585); catalogued as rs868540798, COSV61362898; called by muse, varscan2
- SLC16A10 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs775150850; called by muse, mutect2, varscan2
- SLC1A7 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs748439840; called by muse, mutect2, varscan2
- SLC22A1 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953047014, COSV61453427; called by muse, mutect2
- SLC22A1 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766886919, COSV100266282; called by muse, mutect2
- SLC24A2 | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as rs145253618, COSV53860026; called by muse, mutect2, varscan2
- SLC25A2 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV53404908; called by muse, mutect2, varscan2
- SLC27A5 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1365493197; called by muse, mutect2, varscan2
- SLC28A3 | c.1982C>T p.P661L | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100883315; called by muse, mutect2, varscan2
- SLC30A1 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as rs1204383625; called by muse, mutect2, varscan2
- SLC6A2 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs1341117066; called by muse, mutect2, varscan2
- SLCO6A1 | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as rs769220825, COSV65806886, COSV65809063; called by muse, mutect2, varscan2
- SLFN5 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV55484271; called by muse, mutect2, varscan2
- SOGA1 | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs779139939; called by muse, mutect2, varscan2
- SOGA1 | c.1894C>T p.P632S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs866018502; called by muse, mutect2, varscan2
- SORT1 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs755813424; called by muse, mutect2, varscan2
- SOX5 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs1420871345, COSV58639348; called by muse, mutect2, varscan2
- SPAG1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99309477; called by muse, mutect2
- SPAG17 | c.5807C>T p.S1936F | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as rs1440267069, COSV60455099; called by muse, mutect2, varscan2
- SPO11 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761410004; called by muse, mutect2, varscan2
- SPTLC2 | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.678); catalogued as COSV53638915; called by muse, mutect2, varscan2
- SRCIN1 | c.2323G>A p.E775K (on ENST00000621492; = p.E741K on NM_025248.3) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs747342918; called by muse, mutect2, varscan2
- SS18L1 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100064643; called by muse, mutect2, varscan2
- SSX3 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.394); catalogued as COSV53643015; called by muse, mutect2, varscan2
- ST18 | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs759288853, COSV52494148; called by muse, mutect2, varscan2
- SVOP | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as rs1339150850; called by muse, mutect2, varscan2
- SWT1 | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.361); catalogued as COSV100832948; called by muse, mutect2
- SYTL2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV60359005; called by muse, mutect2, varscan2
- TACC2 | c.8392+1G>A p.X2798_splice (on ENST00000334433; = p.X876_splice on NM_006997.4) | Splice Site (SNP) | VAF 12/95 reads (13%) | catalogued as COSV99587377; called by muse, mutect2, varscan2
- TAS1R2 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1233828125, COSV100946387; called by muse, mutect2, varscan2
- TCP11L2 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as rs146114134; called by muse, mutect2, varscan2
- TECTA | c.4288G>A p.D1430N | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs906326110, COSV50720111; called by muse, mutect2, varscan2
- TEX11 | c.386G>A p.G129E (on ENST00000344304; = p.G114E on NM_031276.3) | Missense Mutation (SNP) | VAF 57/100 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60234168; called by muse, mutect2, varscan2
- TEX13A | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV61171931; called by muse, mutect2, varscan2
- TEX26 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV66839819, COSV66840331; called by muse, mutect2, varscan2
- TFRC | c.2245C>T p.L749F | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1334917022; called by muse, mutect2, varscan2
- THEG | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs765286177, COSV61073226; called by muse, mutect2, varscan2
- THNSL2 | c.1425G>A p.W475* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as rs1285809704; called by muse, mutect2, varscan2
- TIAM1 | c.2259C>A p.N753K | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as rs145603758, COSV54548208; called by muse, mutect2, varscan2
- TICRR | c.3695C>T p.S1232L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1462786279, COSV51545934; called by muse, mutect2, varscan2
- TIGAR | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.376); catalogued as rs1161296093; called by muse, mutect2, varscan2
- TIMM50 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs148698299; called by muse, mutect2, varscan2
- TLK1 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62631256; called by muse, mutect2, varscan2
- TLN2 | c.7613G>A p.R2538K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.983); catalogued as rs1284529768; called by muse, mutect2, varscan2
- TMEM132B | c.3047C>T p.S1016F | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV100170602, COSV54757876; called by muse, mutect2, varscan2
- TMEM132C | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs963992961, COSV59422257, COSV59435631; called by muse, mutect2, varscan2
- TMEM132C | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.392); catalogued as rs867717839, COSV59433766; called by muse, mutect2, varscan2
- TMEM132D | c.2449C>T p.H817Y | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV67158999; called by muse, mutect2, varscan2
- TMEM200A | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.305); catalogued as COSV99758823; called by muse, mutect2, varscan2
- TMPRSS2 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 93/265 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748560513; called by muse, mutect2, varscan2
- TPO | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.663); catalogued as rs755259412; called by muse, mutect2, varscan2
- TRANK1 | c.8252C>T p.S2751F | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.202); catalogued as rs749164015; called by muse, mutect2, varscan2
- TRBV2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 83/246 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs1357020479; called by muse, mutect2, varscan2
- TRIO | c.3805C>T p.P1269S | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.223); catalogued as rs1031853907; called by muse, mutect2, varscan2
- TRIOBP | c.2381C>T p.S794F | Missense Mutation (SNP) | VAF 81/169 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); catalogued as COSV60373483; called by muse, mutect2, varscan2
- TRPM1 | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 85/312 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754571296, COSV56632510; called by muse, mutect2, varscan2
- TRPM6 | c.5022G>A p.W1674* | Nonsense Mutation (SNP) | VAF 95/296 reads (32%) | catalogued as COSV62517227; called by muse, mutect2, varscan2
- TSSK1B | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs770706524, COSV66814886; called by muse, mutect2, varscan2
- UBR4 | c.13255C>T p.L4419F | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766297907; called by muse, mutect2, varscan2
- UBXN10 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 25/84 reads (30%) | catalogued as rs374766447; called by muse, mutect2, varscan2
- UGT2B10 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as COSV55323159; called by muse, mutect2, varscan2
- UGT2B10 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55320864; called by muse, varscan2
- UNC13C | c.5026C>T p.P1676S | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1336571886, COSV52896320, COSV52928758; called by muse, mutect2, varscan2
- USH2A | c.5732G>A p.G1911E | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs763747123; called by muse, mutect2, varscan2
- USP29 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV54238777; called by muse, mutect2, varscan2
- USP5 | c.1948C>T p.P650S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as COSV99978581; called by muse, mutect2
- VCAN | c.2132C>T p.P711L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as COSV99425417; called by muse, mutect2, varscan2
- VCAN | c.8522C>T p.T2841I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); catalogued as COSV54097841; called by muse, mutect2, varscan2
- VTCN1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.19); catalogued as rs771525947; called by muse, mutect2, varscan2
- WDFY4 | c.5219G>A p.S1740N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1203933387; called by muse, mutect2, varscan2
- WDR17 | c.1372del p.R458Efs*39 | Frame Shift Del (DEL) | VAF 30/184 reads (16%) | catalogued as rs1477032650; called by mutect2, pindel*, varscan2
- WNT10A | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs144212422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WNT10A | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.861); catalogued as rs746826999; called by muse, mutect2, varscan2
- XPO6 | c.2450C>T p.S817F | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.648); catalogued as rs755454850; called by muse, mutect2, varscan2
- YIPF2 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs373247637; called by muse, mutect2, varscan2
- ZC3H6 | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV59667046; called by muse, mutect2, varscan2
- ZFP69B | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs759049040, COSV64315044; called by muse, mutect2, varscan2
- ZIM2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55627978, COSV55629293; called by muse, mutect2, varscan2
- ZIM3 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as rs1474392560; called by muse, mutect2, varscan2
- ZNF214 | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as rs866930036, COSV53483500; called by muse, mutect2, varscan2
- ZNF317 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV99926864; called by muse, mutect2, varscan2
- ZNF324B | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868477566; called by muse, mutect2, varscan2
- ZNF385A | c.763C>T p.P255S (on ENST00000338010 / NM_001130967.3; = p.P235S on NM_015481.3) | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs745632022, COSV61493729; called by muse, mutect2, varscan2
- ZNF501 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.796); catalogued as COSV68516177, COSV68516456; called by muse, mutect2, varscan2
- ZNF541 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99645419; called by muse, mutect2, varscan2
- ZNF582 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV100018750; called by muse, mutect2, varscan2
- ZNF609 | c.1661C>T p.S554L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV58581981; called by muse, mutect2, varscan2
- ZNF697 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as rs1192012551; called by muse, mutect2, varscan2
- ZNF80 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.147); catalogued as COSV100352193; called by muse, mutect2, varscan2
- ZNF804A | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.77); catalogued as rs751618831, COSV100168383, COSV56466292; called by muse, mutect2, varscan2
- ZNF804A | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866013097, COSV56433687; called by muse, mutect2, varscan2
- ZNF99 | c.2447C>T p.S816F | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1395315614, COSV68056244; called by muse, mutect2, varscan2
- ABCA7 | c.3907G>A p.E1303K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.81); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABCC3 | c.2512_2532del p.L838_S844del | In Frame Del (DEL) | VAF 16/112 reads (14%) | called by mutect2, pindel
- ABCG2 | c.764G>C p.S255T | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- ACSS2 | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ACTL9 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ACTR5 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS10 | c.1400T>G p.V467G | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- ADAMTS17 | c.2122C>T p.H708Y | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ADAMTSL2 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADCY6 | c.1669C>T p.Q557* | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- ADCY8 | c.2158T>A p.F720I | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- ADGRF5 | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 94/298 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AGL | c.2365T>G p.Y789D | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- AKAP8L | c.819C>T p.T273= | Splice Region (SNP) | VAF 59/142 reads (42%) | called by muse, mutect2, varscan2
- AKAP8L | c.818C>T p.T273I | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- AL645922.1 | c.3557G>A p.G1186E | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALPK1 | c.3596C>T p.S1199F | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALPK3 | c.1877G>A p.G626E | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD18A | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- ANKRD34B | c.1284A>T p.E428D | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AP000350.4 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- APOB | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- ARHGAP22 | c.1193G>A p.G398E | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ARHGAP40 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ARHGAP5 | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ARHGEF10L | c.506G>A p.W169* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- ARID3C | c.983del p.P328Lfs*21 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- ASB15 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- ATG2A | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.04); called by muse, varscan2
- ATM | c.3455C>T p.S1152F | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ATMIN | c.1535G>T p.G512V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP1A4 | c.2262G>A p.M754I | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- ATP2A3 | c.2617T>A p.F873I | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2
- BABAM2 | c.781-1G>A p.X261_splice | Splice Site (SNP) | VAF 26/119 reads (22%) | called by muse, mutect2, varscan2
- BABAM2 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BHMG1 | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- BNC2 | c.1489C>T p.L497F | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- BRINP2 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- BRPF1 | c.2249C>T p.P750L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.027); called by muse, mutect2
- BTBD8 | c.4199C>T p.S1400F (on ENST00000636805 / NM_001376131.1; = p.S887F on NM_015237.4) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- C12orf60 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.084); called by muse, mutect2
- C20orf202 | c.224A>C p.H75P | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- C3 | c.3688G>T p.V1230L | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- C4BPB | c.411G>A p.R137= | Splice Region (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- CA1 | c.236-7C>A | Splice Region (SNP) | VAF 76/270 reads (28%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.1931-1G>A p.X644_splice (on ENST00000356253 / NM_001366867.1; = p.X632_splice on NM_000722.4) | Splice Site (SNP) | VAF 117/268 reads (44%) | called by muse, mutect2, varscan2
- CACNB1 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CADM2 | c.62-2A>G p.X21_splice (on ENST00000407528 / NM_001167674.2; = p.X23_splice on NM_153184.4) | Splice Site (SNP) | VAF 14/33 reads (42%) | called by mutect2, varscan2
- CARF | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CARS2 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CATSPER1 | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CBY2 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- CCDC152 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- CCDC158 | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC168 | c.17360G>A p.G5787E | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC175 | c.1092G>A p.M364I | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC96 | c.268C>G p.P90A | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.026); called by muse, varscan2
- CDCP1 | c.493G>C p.G165R | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CDH12 | c.793A>C p.N265H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDH7 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEACAM3 | c.222T>G p.D74E | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- CERKL | c.1237G>A p.D413N (on ENST00000339098 / NM_001030311.2; = p.D387N on NM_201548.5) | Missense Mutation (SNP) | VAF 68/289 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- CES2 | c.1057-1G>A p.X353_splice | Splice Site (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- CFAP65 | c.392C>T p.P131L (on ENST00000341552 / NM_194302.4; = p.P66L on NM_152389.4) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP92 | c.2561C>T p.P854L | Missense Mutation (SNP) | VAF 84/165 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CFAP92 | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 84/165 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CFHR4 | c.254-1G>A p.X85_splice (on ENST00000367416 / NM_001201551.2; = p.X86_splice on NM_001201550.3) | Splice Site (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- CGN | c.3190G>A p.E1064K | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- CHGB | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CHRNA1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 147/394 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLEC18B | c.1152G>A p.W384* | Nonsense Mutation (SNP) | VAF 20/199 reads (10%) | called by muse, mutect2, varscan2
- CLVS1 | c.444G>A p.W148* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- CNR1 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CNTNAP5 | c.3407G>A p.R1136K | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL13A1 | c.1900G>A p.G634R (on ENST00000398978 / NM_001130103.2; = p.G562R on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL16A1 | c.4292G>A p.G1431E | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- COL16A1 | c.4291G>A p.G1431R | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- COL19A1 | c.2561G>A p.G854D | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL20A1 | c.2986C>T p.L996F | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- COL21A1 | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.12); called by muse, mutect2
- COL21A1 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- COL22A1 | c.4234C>T p.Q1412* | Nonsense Mutation (SNP) | VAF 44/155 reads (28%) | called by muse, mutect2, varscan2
- COL25A1 | c.780+1G>A p.X260_splice | Splice Site (SNP) | VAF 17/97 reads (18%) | called by muse, mutect2, varscan2
- COL25A1 | c.780G>A p.K260= | Splice Region (SNP) | VAF 17/97 reads (18%) | called by muse, mutect2, varscan2
- COL3A1 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 58/256 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.728); called by muse, varscan2
- COL3A1 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 63/259 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- COL4A4 | c.1205-1G>A p.X402_splice | Splice Site (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- COL6A3 | c.1643G>A p.G548E | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- COL7A1 | c.5597G>A p.G1866E | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL8A2 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL9A3 | c.1760G>A p.G587E | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CPEB4 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- CPPED1 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CROT | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 112/160 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRX | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CSMD1 | c.4706G>A p.G1569E (on ENST00000520002; = p.G1568E on NM_033225.6) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSMD3 | c.3655G>A p.E1219K (on ENST00000297405 / NM_001363185.1; = p.E1115K on NM_052900.3) | Missense Mutation (SNP) | VAF 110/211 reads (52%) | SIFT tolerated (0.94); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CST2 | c.245A>G p.N82S | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); called by muse, varscan2
- CTNNA1 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- CWH43 | c.1942G>A p.D648N | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- CYP11A1 | c.1094G>A p.G365E | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- CYP39A1 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- DAB2IP | c.2744G>A p.R915K (on ENST00000408936; = p.R887K on NM_032552.3) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DCDC2 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DDHD2 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DEPDC5 | c.1780C>T p.Q594* | Nonsense Mutation (SNP) | VAF 15/155 reads (10%) | called by muse, mutect2
- DERA | c.939T>A p.H313Q | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2
- DGCR8 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 122/237 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DGKD | c.280G>A p.D94N (on ENST00000264057 / NM_152879.3; = p.D50N on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- DNAH7 | c.2821G>A p.D941N | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH8 | c.11545C>T p.P3849S | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.10211G>A p.R3404K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOCK10 | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSC3 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- DSCAM | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DTHD1 | c.1213C>T p.H405Y (on ENST00000456874; = p.H240Y on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- DTL | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DUOX2 | c.4525-2A>C p.X1509_splice | Splice Site (SNP) | VAF 54/183 reads (30%) | called by muse, mutect2, varscan2
- DYTN | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ECT2L | c.1939G>A p.G647R | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- EEF1A2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.142); called by mutect2, varscan2
- ELOVL2 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- ELP1 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- EMILIN2 | c.1552C>A p.P518T | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ENHO | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- EPB41L3 | c.2713G>A p.G905R | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHA6 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- EPHB6 | c.2721_2754del p.H908* | Frame Shift Del (DEL) | VAF 22/191 reads (12%) | called by mutect2, pindel
- ERICH6B | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EVPLL | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EXPH5 | c.3875C>T p.A1292V | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- FAM13C | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.063); called by muse, mutect2
- FAM193A | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FAM83A | c.1034G>A p.G345D | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FAT1 | c.9311G>A p.G3104E | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- FAT2 | c.7153G>A p.E2385K | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- FAT3 | c.12164G>A p.R4055K | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBLN2 | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FBXO16 | c.215T>A p.F72Y | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FBXO22 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 93/245 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FBXO38 | c.1118T>G p.V373G | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- FER1L5 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FETUB | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 25/38 reads (66%) | called by muse, mutect2, varscan2
- FGD5 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FLT4 | c.2728G>A p.V910I | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSD2 | c.411G>A p.W137* | Nonsense Mutation (SNP) | VAF 45/152 reads (30%) | called by muse, mutect2, varscan2
- GABRA1 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 79/224 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- GABRA2 | c.703G>A p.G235S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAPVD1 | c.1135C>T p.L379F | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GARRE1 | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GCM2 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- GET4 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- GLB1 | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GLDN | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPC6 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); called by muse, varscan2
- GPR141 | c.119T>A p.F40Y | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GREB1 | c.3227T>C p.V1076A | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIK1 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- GRIN2B | c.3431C>T p.P1144L | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GYS2 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAPLN3 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- HCAR3 | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- HECTD2 | c.2309C>T p.S770L | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- HECTD4 | c.3853G>A p.D1285N | Missense Mutation (SNP) | VAF 279/524 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- HEMK1 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIVEP2 | c.5885C>T p.S1962F | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- HMCN2 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPM | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HOXA3 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 97/177 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- HPS1 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IGF1R | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 79/277 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- IL16 | c.3304G>A p.E1102K (on ENST00000302987 / NM_172217.5; = p.E401K on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IL36G | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IL6R | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INAVA | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ISG20L2 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ITGA4 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ITPR2 | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITPRID2 | c.2197C>T p.P733S | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IZUMO1R | c.644T>G p.V215G (on ENST00000440961; = p.V222G on NM_001199206.3) | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNA4 | c.1402G>A p.G468S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNK1 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- KCNN4 | c.1050-7C>T | Splice Region (SNP) | VAF 24/96 reads (25%) | called by muse, mutect2, varscan2
- KCNU1 | c.3164C>T p.S1055L | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCTD8 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- KIDINS220 | c.3311C>T p.S1104F | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KIF21A | c.2591C>T p.S864F (on ENST00000361418 / NM_001378440.1; = p.S851F on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- KIF5C | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by mutect2, varscan2
- KLB | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- KLF14 | c.267G>T p.W89C | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- KLHL20 | c.1186G>C p.V396L | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- KLHL40 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2
- KRIT1 | c.2149C>T p.L717F | Missense Mutation (SNP) | VAF 108/306 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- KRT71 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP13-1 | c.351C>A p.C117* | Nonsense Mutation (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- LAD1 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.02); called by mutect2, varscan2
- LAMA1 | c.5063C>T p.P1688L | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LDLRAD1 | c.339C>T p.C113= | Splice Region (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- LGALS16 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LGR5 | c.427C>T p.L143= | Splice Region (SNP) | VAF 32/99 reads (32%) | called by muse, mutect2, varscan2
- LGR5 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LHX8 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRCH1 | c.2092C>T p.L698F | Missense Mutation (SNP) | VAF 105/292 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1 | c.2215G>A p.G739S | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- LRP1 | c.6262G>A p.E2088K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- LRP2 | c.12737G>A p.W4246* | Nonsense Mutation (SNP) | VAF 65/211 reads (31%) | called by muse, mutect2, varscan2
- LRPPRC | c.591+2T>G p.X197_splice | Splice Site (SNP) | VAF 137/348 reads (39%) | called by muse, mutect2, varscan2
- LRRC46 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- LRRC7 | c.3360G>A p.M1120I (on ENST00000651989 / NM_001370785.2; = p.M1087I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- MAGEC1 | c.1779C>G p.H593Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- MAGEL2 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- MAP1B | c.4739C>T p.S1580F | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAP2 | c.4087G>A p.E1363K | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- MAP3K11 | c.840G>A p.M280I | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- MAP7D2 | c.1247A>T p.E416V | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARCHF2 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- MAST2 | c.4642C>T p.P1548S | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MDN1 | c.3054T>G p.N1018K | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ME3 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- METTL11B | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 26/106 reads (25%) | called by muse, mutect2, varscan2
- MICU2 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MIDEAS | c.2452dup p.H818Pfs*14 | Frame Shift Ins (INS) | VAF 28/170 reads (16%) | called by mutect2, pindel, varscan2
- MMP1 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- MMP11 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 117/214 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MMP28 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- MMRN2 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 34/105 reads (32%) | called by muse, mutect2, varscan2
- MOG | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.95); PolyPhen probably damaging (1); called by muse, mutect2
- MOV10 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MOV10 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MPHOSPH9 | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MPO | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTARC1 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- MUC16 | c.32975T>C p.V10992A | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MUC17 | c.10141C>T p.P3381S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MUC20 | c.1990C>T p.L664F | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC5B | c.4732A>C p.N1578H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC5B | c.4966G>A p.G1656R | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MUC5B | c.15656G>A p.G5219D | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYH14 | c.5675G>A p.G1892E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- MYH2 | c.2550A>T p.E850D | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, varscan2
- MYH7 | c.5771G>A p.S1924N | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- MYH8 | c.4477G>A p.E1493K | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYL1 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, varscan2
- MYO18A | c.6018C>T p.S2006= | Splice Region (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- MYO18A | c.6017C>T p.S2006F | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- MYO9B | c.3341C>G p.S1114C | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- N4BP2 | c.3379G>A p.D1127N | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAA35 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 30/133 reads (23%) | called by muse, mutect2, varscan2
- NCAN | c.2834C>T p.S945F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NCKAP1L | c.1412T>C p.L471P | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NCKAP5 | c.4597G>A p.E1533K | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- NECAB2 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NECTIN3 | c.1550del p.G517Efs*2 | Frame Shift Del (DEL) | VAF 35/90 reads (39%) | called by mutect2, pindel, varscan2
- NIPBL | c.8081C>T p.S2694F | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NLRP10 | c.1082G>T p.C361F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOS1AP | c.345G>A p.R115= | Splice Region (SNP) | VAF 45/231 reads (19%) | called by muse, mutect2, varscan2
- NOTCH4 | c.2335G>A p.G779R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NUTM2A | c.2441C>T p.P814L | Missense Mutation (SNP) | VAF 53/305 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NWD1 | c.1900C>T p.L634F | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- NWD2 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NYAP2 | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NYNRIN | c.4822C>T p.L1608F | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- OOEP | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR2A12 | c.88T>C p.F30L | Missense Mutation (SNP) | VAF 144/188 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OR4F15 | c.882G>T p.M294I | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- OR4X1 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- OR51I1 | c.908A>C p.K303T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- OR5P2 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- OR7A17 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.187); called by muse, mutect2, varscan2
885 further variants in this file (193 protein-altering or splice-affecting, 461 silent, 231 other) are not listed here.
